FM case AD3572 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/45d39860-05bb-4a64-ae2a-1a5bc067e9d1

Female, 30.5 years: Pituitary adenoma, NOS (ICD-O-3 8272/0) of the pituitary gland; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
